Gene-level copy-number profile of tumor specimen TCGA-OR-A5JL-01A from TCGA case TCGA-OR-A5JL, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 36.0 years (13,155 days).
Specimen TCGA-OR-A5JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f70dee4f-4b68-46e2-8734-ad3b59507552.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d6bade64-0651-4427-94ad-2b1d97cef89c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 62; copy number 2: 35,176; copy number 3: 2,762; copy number 4: 20,883; copy number 5: 248; copy number 6: 689.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JL-01A-11D-A29H-01): tumor purity 0.82, ploidy 1.42, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 937 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:183,418,890–187,060,930, 91 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:68,421,698–70,032,366, 39 genes, copy number 5: PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1, AL359317.2, EXD2, AL359317.1, GALNT16, AL157996.1, ERH, SLC39A9, AL157996.2, PLEKHD1, AL133445.1, CCDC177, AL133445.3, SUSD6, AL133445.2, SRSF5, SLC10A1, AL157789.1, SMOC1, RPL7AP6.
- chr14:76,495,363–77,320,883, 35 genes, copy number 6 (within-gene range 4–6): AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2.
- chr14:81,175,452–82,430,156, 17 genes, copy number 5 (within-gene range 4–5): GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP.
- chr14:86,936,640–106,875,071, 755 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 62. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
